Somatic mutation profile of tumor specimen TCGA-KB-A93H-01A (aliquot TCGA-KB-A93H-01A-11D-A397-08) from TCGA case TCGA-KB-A93H, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 79.3 years (28,966 days).
Specimen TCGA-KB-A93H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f449edb-97c0-4e56-b095-fecee631cd99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KB-A93H-10A (Blood Derived Normal), aliquot TCGA-KB-A93H-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8f63da-e795-4185-8b58-9b38fc4925c7

The open-access MAF lists 232 somatic variants for this specimen: 166 protein-altering or splice-affecting, 61 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 61, Nonsense Mutation 9, Intron 3, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 113/224 reads (50%) | catalogued as rs587783592, CM980536, COSV57575875; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1603C>G p.P535A | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54029186, COSV99566107; called by muse, mutect2, varscan2
- ABL1 | c.1803C>A p.S601R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.706); catalogued as rs780716188, COSV100584087, COSV100584202; called by muse, mutect2, varscan2
- ACSL6 | c.991C>G p.Q331E (on ENST00000379240; = p.Q356E on NM_001009185.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.06); catalogued as COSV99734055; called by muse, mutect2
- ADAMTS12 | c.1385A>G p.K462R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100711210; called by muse, mutect2, varscan2
- ADGRB3 | c.3599T>C p.L1200P | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53263692, COSV99485745; called by muse, mutect2, varscan2
- ADGRL2 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99589795; called by muse, mutect2, varscan2
- AFF2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV100650376; called by muse, mutect2
- APEX2 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs948894054, COSV100238447; called by muse, mutect2, varscan2
- AR | c.2585A>G p.K862R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as rs750930905, COSV101018617; called by muse, mutect2, varscan2
- ARC | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100751731; called by muse, mutect2, varscan2
- ARMC6 | c.1441G>A p.D481N (on ENST00000392336; = p.D456N on NM_033415.4) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523080; called by muse, mutect2, varscan2
- ARMCX3 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.369); catalogued as COSV100362297; called by muse, varscan2
- ATP2B4 | c.2740C>T p.R914C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1558051227, COSV100397684; called by muse, mutect2, varscan2
- CCDC59 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99810710; called by muse, mutect2
- CD101 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV56716863, COSV99869832; called by muse, mutect2, varscan2
- CD5L | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV63821114, COSV63822042; called by muse, mutect2, varscan2
- CEP83 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100352948; called by muse, mutect2
- CMPK2 | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99878893; called by muse, mutect2, varscan2
- COMMD5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs141500693, COSV100295811; called by muse, mutect2
- CORIN | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903866; called by muse, mutect2, varscan2
- CPB2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs374776365, COSV51675416; called by muse, mutect2, varscan2
- CYP7A1 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100052451, COSV56964752; called by muse, mutect2, varscan2
- DCAF12L2 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100758441; called by muse, mutect2, varscan2
- DIAPH2 | c.2081A>C p.K694T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100233527; called by muse, mutect2, varscan2
- DMD | c.8426G>A p.R2809H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs778331600, COSV100627981; ClinVar: uncertain significance; called by muse, mutect2
- DPP10 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV100068122; called by muse, mutect2, varscan2
- DYNC1H1 | c.7928G>A p.R2643H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100794663, COSV64137932; called by muse, mutect2, varscan2
- ELAVL4 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100836778; called by muse, mutect2
- EPHA10 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs146430998, COSV60405112; called by muse, mutect2, varscan2
- ERICH1 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV50641787; called by muse, mutect2, varscan2
- FAM135B | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371281620; called by muse, mutect2, varscan2
- FCHO1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs531090742, COSV53186153; called by muse, mutect2, varscan2
- FOLH1 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs143235150; called by muse, mutect2, varscan2
- GABRA2 | c.1162T>C p.S388P | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as COSV100734448; called by muse, mutect2, varscan2
- GALK2 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100508995; called by muse, mutect2, varscan2
- GALNT8 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362946; called by muse, mutect2, varscan2
- GOLGA3 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as rs748737914, COSV99209929; called by muse, mutect2
- GRAMD1C | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV100822932; called by muse, mutect2
- GRIA1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs760982517, COSV53601131; called by muse, mutect2, varscan2
- GRM5 | c.2774G>A p.R925Q (on ENST00000305447 / NM_001143831.2; = p.R893Q on NM_000842.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs746209459, COSV59588578, COSV59593630, COSV59599340; called by muse, mutect2, varscan2
- GSPT2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100468222; called by muse, mutect2, varscan2
- GUCY2F | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1359713779, COSV99485219; called by muse, mutect2
- HAS1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55788251; called by muse, mutect2, varscan2
- HECW1 | c.666T>A p.F222L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101223889; called by muse, mutect2, varscan2
- HOXA1 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029055; called by muse, mutect2, varscan2
- HSD3B2 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV65593272; called by muse, mutect2
- IFNA2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV66505875; called by muse, mutect2, varscan2
- KCNA6 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54974128, COSV99768741; called by muse, mutect2, varscan2
- KCNJ8 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1341531219, COSV53718635; called by muse, mutect2, varscan2
- KCNT2 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54071938, COSV54102577; called by muse, mutect2, varscan2
- KRTAP19-7 | c.149A>T p.H50L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV100603208; called by muse, mutect2, varscan2
- LAMA1 | c.4066G>T p.A1356S | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056785; called by muse, mutect2, varscan2
- LAMA4 | c.1232T>G p.L411R (on ENST00000230538 / NM_001105206.3; = p.L404R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100038723, COSV57897029; called by muse, mutect2, varscan2
- LCE2C | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV100909446; called by muse, mutect2, varscan2
- LILRB1 | c.914C>G p.A305G (on ENST00000427581; = p.A269G on NM_006669.6) | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV100207441; called by muse, mutect2
- LRRC7 | c.830A>G p.K277R (on ENST00000651989 / NM_001370785.2; = p.K244R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99227844; called by muse, mutect2, varscan2
- LRRK2 | c.4499T>C p.L1500P | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110605; called by muse, mutect2, varscan2
- MAFB | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100965054; called by muse, mutect2, varscan2
- MAGEB6B | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs1029223648; called by muse, mutect2
- MAGEC1 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV53573628; called by muse, mutect2, varscan2
- MAGEE1 | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100819433; called by muse, mutect2, varscan2
- MAGEE1 | c.2308G>T p.G770* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100819435; called by muse, mutect2, varscan2
- MAP4 | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 92/124 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV100805959; called by muse, mutect2, varscan2
- MED12 | c.1746G>A p.T582= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as rs773240125, COSV61350517; called by muse, mutect2
- MERTK | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV99774837; called by muse, mutect2, varscan2
- MOSPD2 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as rs775680398, COSV100996836; called by muse, mutect2, varscan2
- MROH5 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101436038; called by muse, mutect2, varscan2
- MTBP | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100012275; called by muse, mutect2, varscan2
- MUC16 | c.17527A>C p.T5843P | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.354); catalogued as COSV101200295; called by muse, mutect2, varscan2
- MYEF2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372821159; called by muse, mutect2, varscan2
- MYH7B | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99482933; called by muse, mutect2, varscan2
- NAALAD2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428564; called by muse, mutect2, varscan2
- NLRC3 | c.945A>C p.Q315H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100072962; called by muse, mutect2, varscan2
- NOD2 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV100318668; called by muse, mutect2, varscan2
- NPTX2 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99674972; called by muse, mutect2, varscan2
- NRK | c.2405A>C p.K802T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs992337051, COSV99688275; called by muse, mutect2, varscan2
- NUAK2 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs752932851, COSV65681758; called by muse, mutect2, varscan2
- OLFM3 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs762702992, COSV100919803; called by muse, mutect2, varscan2
- ONECUT1 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); catalogued as COSV100009296; called by muse, mutect2, varscan2
- OR10G7 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs150421981; called by muse, mutect2, varscan2
- OR10K1 | c.527A>C p.H176P | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99193725; called by muse, mutect2, varscan2
- OR10K2 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149545; called by mutect2, varscan2
- OR2T33 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773123240, COSV100532083; called by muse, mutect2, varscan2
- OR4C16 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.41); catalogued as COSV100114124; called by muse, mutect2, varscan2
- OR4C16 | c.739T>A p.L247M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV100114128, COSV58940642; called by muse, mutect2, varscan2
- OR4C46 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100060788, COSV60218272; called by muse, mutect2, varscan2
- OR4K17 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59647915; called by muse, mutect2, varscan2
- P2RY8 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1336332515, COSV67178150, COSV67178583; called by muse, mutect2, varscan2
- PABPC5 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100442485; called by muse, mutect2
- PARP4 | c.3447G>A p.E1149= | Splice Region (SNP) | VAF 21/177 reads (12%) | catalogued as COSV101131740; called by muse, mutect2, varscan2
- PAX7 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as rs568673882, CM148742, COSV100946759; called by muse, mutect2, varscan2
- PC | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs112948607, COSV100547079; called by muse, mutect2, varscan2
- PCDH7 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV62338742; called by muse, mutect2, varscan2
- PCDHA8 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100970831; called by muse, mutect2, varscan2
- PCDHB4 | c.1446C>A p.N482K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782505038, COSV52020858, COSV99522313; called by muse, varscan2
- PCDHGB6 | c.687A>C p.E229D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as COSV99541139; called by muse, mutect2
- PCK1 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100618; called by muse, mutect2, varscan2
- PDS5A | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100337459; called by muse, mutect2, varscan2
- PHC2 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV99931172; called by muse, mutect2, varscan2
- PHRF1 | c.2396C>T p.T799M (on ENST00000264555 / NM_001286581.2; = p.T798M on NM_020901.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776171251, COSV99204899; called by muse, mutect2, varscan2
- PI15 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.11); catalogued as COSV52639533, COSV52640021; called by muse, mutect2, varscan2
- PLXNA3 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.199); catalogued as rs782726215, COSV100860055; called by muse, mutect2, varscan2
- PMM2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs769336029, COSV99191158; called by mutect2, varscan2
- POLR1A | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as rs747621114, COSV99806934; called by muse, mutect2, varscan2
- PPEF1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs767043387, COSV100583860; called by muse, mutect2, varscan2
- PPP1R15B | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65815399; called by muse, mutect2, varscan2
- PPP4R2 | c.439T>G p.L147V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.159); catalogued as COSV99866154; called by muse, mutect2, varscan2
- PRAMEF17 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV101068752; called by muse, mutect2, varscan2
- PRR16 | c.398A>C p.K133T (on ENST00000407149 / NM_001300783.2; = p.K110T on NM_016644.2) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV101087446; called by muse, mutect2, varscan2
- PRSS12 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99628443; called by muse, mutect2, varscan2
- RABL2B | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as rs559977293; ClinVar: likely benign; called by muse, mutect2, varscan2
- REPS2 | c.605A>C p.H202P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV100381295; called by muse, mutect2, varscan2
- ROBO2 | c.3956G>T p.S1319I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV100167710; called by muse, mutect2, varscan2
- RP1 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99607928; called by muse, mutect2, varscan2
- RSL1D1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100851996; called by muse, mutect2, varscan2
- RUNDC3B | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100407100, COSV56690862; called by muse, mutect2, varscan2
- SCUBE3 | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs761271869, COSV99234657; called by muse, mutect2, varscan2
- SEMA3C | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99543236; called by muse, mutect2, varscan2
- SF3B3 | c.3323C>T p.T1108M | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1318359923, COSV100210011; called by muse, mutect2, varscan2
- SH3GL3 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as rs1021145699, COSV100196966; called by muse, mutect2, varscan2
- SHANK3 | c.3322C>T p.R1108* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99437249; called by muse, mutect2
- SLC17A6 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV99581750; called by muse, mutect2, varscan2
- SLC6A18 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as rs772503347, COSV57250523, COSV99722435; called by muse, mutect2, varscan2
- SLCO2A1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1196094121, COSV100189086; called by muse, mutect2, varscan2
- SOX3 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866405686, COSV65167938; called by muse, mutect2, varscan2
- SPATA19 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100141155; called by muse, mutect2
- SPEM1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs554830915, COSV100081120; called by muse, mutect2, varscan2
- SPIN2A | c.657A>C p.E219D | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.839); catalogued as COSV100888062; called by muse, mutect2, varscan2
- SPTB | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as rs138841945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STXBP5 | c.1143T>C p.N381= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs962005001, COSV99470515; called by muse, mutect2, varscan2
- SULF1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1407025182, COSV99483403; called by muse, mutect2, varscan2
- TAF7 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1488233716, COSV100515024; called by muse, mutect2, varscan2
- TAOK1 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594502, COSV99914272; called by muse, mutect2, varscan2
- TCEAL5 | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013150; called by muse, mutect2
- TENM3 | c.7733C>T p.T2578M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs760930126, COSV69314886; called by muse, mutect2, varscan2
- TENT5D | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100382810, COSV100382949; called by muse, mutect2, varscan2
- THRB | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1029651348, COSV99769564; called by muse, mutect2, varscan2
- TIMD4 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs868636588, COSV99192706; called by muse, mutect2
- TP53 | c.403del p.C135Afs*35 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | catalogued as COSV52674321, COSV52706302, COSV52827707; called by mutect2, pindel, varscan2
- TPTE | c.362A>G p.Y121C (on ENST00000618007 / NM_199261.4; = p.Y103C on NM_199259.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs556974504; called by muse, varscan2
- TRIM33 | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100635489; called by muse, mutect2, varscan2
- TRPC5 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53287159; called by muse, mutect2, varscan2
- TTN | c.4077A>C p.E1359D (on ENST00000591111; = p.E1313D on NM_003319.4) | Missense Mutation (SNP) | VAF 32/61 reads (52%) | PolyPhen probably damaging (0.99); catalogued as COSV60042736; called by muse, mutect2, varscan2
- TUBA3C | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV101262805, COSV67138962; called by muse, mutect2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- VCAN | c.7049C>G p.P2350R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV99426323, COSV99427640; called by muse, mutect2, varscan2
- VCAN | c.8093A>C p.K2698T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs770058352, COSV99426326; called by muse, mutect2, varscan2
- WDR17 | c.854T>A p.I285K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV99707824; called by muse, mutect2, varscan2
- ZFP28 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100019683; called by muse, mutect2, varscan2
- ZFPM2 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as rs1160935850, COSV101023291; called by muse, mutect2
- ZFPM2 | c.1244T>G p.L415W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV101023293; called by muse, mutect2, varscan2
- ZNF43 | c.1776A>C p.K592N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100731857; called by muse, mutect2, varscan2
- ZNF473 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV99568930; called by muse, mutect2
- ZNF592 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100245936; called by muse, mutect2, varscan2
- ZNF613 | c.531C>G p.N177K (on ENST00000293471 / NM_001031721.4; = p.N141K on NM_024840.4) | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99522992; called by muse, mutect2, varscan2
- ZNF808 | c.243T>A p.N81K | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.243); catalogued as COSV100708040; called by muse, mutect2
- ZNF816 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV99554619; called by muse, mutect2, varscan2
- CD99L2 | c.634_636del p.K212del | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- FRG2 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- HNRNPA1 | c.418dup p.R140Pfs*15 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SSH2 | c.1626dup p.E543* | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- TMEM64 | c.628C>G p.H210D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TPTE | c.344T>C p.F115S (on ENST00000618007 / NM_199261.4; = p.F97S on NM_199259.4) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, varscan2
- WDR1 | c.1406del p.V469Afs*11 (on ENST00000382452; = p.V329Afs*11 on NM_005112.5) | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- ABCC6 | c.2454C>T p.P818= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99229052; called by muse, mutect2, varscan2
- ADGRL3 | c.3228A>C p.T1076= (on ENST00000506720 / NM_001322402.2; = p.T1008= on NM_015236.6) | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101547244; called by muse, mutect2, varscan2
- AKAP6 | c.1266C>T p.S422= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99801945; called by muse, mutect2, varscan2
- ALG10 | c.1125A>T p.P375= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV56794348; called by muse, mutect2, varscan2
- ARMC4 | c.2070G>A p.Q690= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100537022; called by muse, mutect2, varscan2
- ARMCX3 | c.270T>G p.A90= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV100362296; called by muse, varscan2
- ASH1L | c.6993G>A p.E2331= (on ENST00000368346 / NM_001366177.2; = p.E2326= on NM_018489.3) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100853483; called by muse, mutect2, varscan2
- BCL11A | c.1368C>T p.D456= (on ENST00000335712 / NM_001365609.1; = p.D490= on NM_018014.4) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100185901; called by muse, mutect2, varscan2
- BRCA1 | c.231G>A p.T77= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs80356847, CS1111248, COSV58792582; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDX60L | c.1284G>A p.S428= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1222098251, COSV52713909; called by muse, mutect2, varscan2
- DES | c.1146C>T p.A382= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100900464; called by muse, mutect2, varscan2
- DRD5 | c.855C>T p.R285= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs201697048, COSV58577368; called by muse, mutect2, varscan2
- DSEL | c.2877A>G p.Q959= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100025798; called by muse, mutect2, varscan2
- ELFN2 | c.654G>A p.P218= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs149082389; called by muse, mutect2, varscan2
- EPHB1 | c.2085C>T p.I695= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs941921522, COSV101213374; called by muse, mutect2, varscan2
- FOXG1 | c.564G>A p.A188= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100486676, COSV100486912; called by muse, varscan2
- GABRQ | c.1431T>C p.I477= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- GLI3 | c.2217A>G p.G739= | Silent (SNP) | VAF 51/91 reads (56%) | catalogued as COSV101229926; called by muse, mutect2, varscan2
- GLUD2 | c.582C>G p.T194= | Silent (SNP) | VAF 42/131 reads (32%) | catalogued as COSV100046910, COSV60151158; called by muse, mutect2, varscan2
- GPRASP1 | c.2301A>G p.E767= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100851027; called by muse, mutect2
- HCN3 | c.415C>T p.L139= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100855711; called by muse, mutect2, varscan2
- HSD3B2 | c.342C>T p.A114= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV101027504; called by muse, mutect2
- INTS5 | c.2304T>C p.N768= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV100399689; called by muse, mutect2, varscan2
- IRX2 | c.315C>T p.S105= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1253991139, COSV100121771; called by muse, mutect2, varscan2
- KIAA1210 | c.2586T>G p.T862= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV68176324, COSV68176710; called by muse, mutect2, varscan2
- LAMP1 | c.78G>A p.A26= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs766554441, COSV60211232, COSV60212040; called by muse, mutect2, varscan2
- MAGEB6B | c.180T>G p.V60= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV69689983; called by muse, mutect2
- MAST4 | c.2181C>T p.Y727= (on ENST00000403625 / NM_001164664.2; = p.Y538= on NM_015183.3) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs772692846, COSV99844584; called by muse, mutect2, varscan2
- MED13L | c.4398C>T p.R1466= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs368928526; called by muse, mutect2, varscan2
- MMP27 | c.933G>A p.T311= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs775697885, COSV52783097, COSV99498508; called by muse, mutect2, varscan2
- MRC1 | c.2991C>G p.T997= | Silent (SNP) | VAF 42/343 reads (12%) | called by muse, mutect2, varscan2
- NME8 | c.1740A>G p.R580= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99553479; called by muse, mutect2, varscan2
- NOVA1 | c.939G>T p.V313= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99947948; called by muse, mutect2, varscan2
- NRG3 | c.279C>T p.S93= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100931986; called by muse, mutect2, varscan2
- OPHN1 | c.1182C>T p.I394= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV62782464, COSV62783446, COSV62784904; called by muse, mutect2, varscan2
- PCDH17 | c.711C>T p.N237= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs746552268, COSV64974193; called by muse, mutect2, varscan2
- PROX1 | c.798G>A p.S266= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV54778739, COSV99799674; called by muse, mutect2, varscan2
- PTPN4 | c.1182G>A p.P394= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs140598634; called by muse, mutect2, varscan2
- PTPRD | c.1467T>A p.S489= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100645387; called by muse, mutect2, varscan2
- PTPRT | c.1048C>T p.L350= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV100628373, COSV61999714; called by muse, mutect2, varscan2
- QRICH2 | c.651C>T p.V217= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99429375; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2319C>T p.P773= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1328881593, COSV54762419; called by muse, mutect2, varscan2
- RAPGEF2 | c.132C>T p.S44= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100031332; called by muse, mutect2, varscan2
- RELN | c.8370C>T p.V2790= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100634072; called by muse, mutect2, varscan2
- RIMS2 | c.4260G>A p.L1420= (on ENST00000666250 / NM_001348490.2; = p.L991= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs760190206, COSV51652525; called by muse, mutect2, varscan2
- RRP15 | c.93A>C p.V31= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1365010865, COSV100860761; called by muse, mutect2, varscan2
- SEMA6D | c.2941T>C p.L981= (on ENST00000316364 / NM_153618.2; = p.L919= on NM_020858.2) | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV60373388, COSV60376846; called by muse, mutect2, varscan2
- SMARCD3 | c.504G>A p.A168= (on ENST00000262188 / NM_001003801.2; = p.A155= on NM_003078.4) | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs200087546, COSV50388944, COSV50394123; called by muse, mutect2, varscan2
- SPTY2D1 | c.753T>G p.P251= | Silent (SNP) | VAF 43/159 reads (27%) | catalogued as COSV100311730; called by muse, mutect2, varscan2
- SYNE1 | c.7869T>C p.L2623= (on ENST00000367255 / NM_182961.4; = p.L2630= on NM_033071.3) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99569202; called by muse, mutect2, varscan2
- THBD | c.954C>T p.A318= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs754792536, COSV101001895; called by mutect2, varscan2
- TMEM131L | c.2880C>A p.I960= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs779256807, COSV99547685; called by muse, mutect2, varscan2
- TPR | c.1128C>T p.A376= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs377515093, COSV66601840; called by mutect2, varscan2
- TRIML2 | c.1014A>G p.K338= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV58714561, COSV58718244, COSV58720356; called by muse, mutect2, varscan2
- TRIML2 | c.408G>C p.L136= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100456163; called by muse, mutect2
- TRPC4 | c.258C>T p.I86= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs1233301242, COSV100157130; called by muse, mutect2, varscan2
- TTPA | c.453G>T p.R151= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV99478547; called by muse, mutect2, varscan2
- USP4 | c.600C>T p.N200= | Silent (SNP) | VAF 58/80 reads (73%) | catalogued as COSV99649429; called by muse, mutect2, varscan2
- ZBTB49 | c.843G>T p.V281= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100552505; called by muse, mutect2, varscan2
- ZIC1 | c.615C>T p.A205= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs964037096, COSV99292085; called by muse, mutect2
- ZNF560 | c.765C>T p.Y255= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1490665477; called by muse, mutect2
- DCHS2 | n.3248C>T | RNA (SNP) | VAF 18/88 reads (20%) | catalogued as rs146199349, COSV59719374; called by muse, mutect2, varscan2
- KIF16B | c.3498+3209A>C | Intron (SNP) | VAF 38/169 reads (22%) | catalogued as COSV100734511; called by muse, mutect2, varscan2
- OSBPL6 | c.987+4574T>A | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99507823; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302052 T>C | 5'Flank (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- VGLL1 | c.688+80del | Intron (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
